Gene-level copy-number profile of tumor specimen TCGA-QQ-A8VF-01A from TCGA case TCGA-QQ-A8VF, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 70.3 years (25,682 days).
Specimen TCGA-QQ-A8VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f286cc79-b188-4ff9-9a16-d8f100d772f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QQ-A8VF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a5f529c4-bca9-43d7-9bcf-1721fde3457a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,415; copy number 2: 38,839; copy number 3: 6,985; copy number 4: 11,677; copy number 5: 459; copy number 6: 270; copy number 7: 121; copy number 8: 2; copy number 9: 10; copy number 10: 7; copy number 12: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QQ-A8VF-01A-11D-A37B-01): tumor purity 0.79, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,478,736–5,554,881, 4 genes: Z98259.3, Z98259.2, Z98259.1, Z97988.2.
- chr1:5,564,071–5,564,143, 1 gene: Z97988.1.
- chr13:89,141,800–89,280,240, 4 genes (within-gene range 0–2): AL162573.1, LINC00440, LINC01047, TRIM60P13.
- chr19:55,999,726–56,217,777, 11 genes: NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 884 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:7,226,156–31,329,146, 320 genes, copy number 5 (broad region; genes not listed).
- chr7:44,503,773–44,541,330, 3 genes, copy number 9: RNU6-1097P, AC004938.1, NPC1L1.
- chr7:124,742,312–124,790,689, 3 genes, copy number 9: AC004925.1, GPR37, C7orf77.
- chr7:141,392,155–141,416,390, 2 genes, copy number 8: AC005692.3, AC005692.1.
- chr7:142,871,208–144,380,632, 80 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:144,451,941–148,420,998, 17 genes, copy number 5–10 (within-gene range 2–17): TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr12:80,402,178–80,719,671, 5 genes, copy number 7 (within-gene range 3–7): PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5.
- chr18:12,991,362–15,330,282, 80 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:28,435,388–28,727,680, 1 gene, copy number 5 (within-gene range 4–5): AC005394.2.
- chr19:28,491,864–28,632,728, 1 gene, copy number 5 (within-gene range 4–5): AC005394.1.
- chr19:28,602,379–29,298,576, 18 genes, copy number 5: AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4.
- chr19:35,399,511–35,451,767, 6 genes, copy number 6: LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2.
- chr19:37,217,926–37,906,677, 30 genes, copy number 7: ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.
- chr19:37,963,853–37,964,790, 1 gene, copy number 7: AC008395.1.
- chr19:38,244,035–38,292,615, 1 gene, copy number 6 (within-gene range 3–6): SPINT2.
- chr19:38,289,151–43,171,515, 263 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:48,926,171–49,151,026, 33 genes, copy number 5 (within-gene range 3–5): AC026803.1, DHDH, BAX, AC026803.2, FTL, GYS1, RUVBL2, MIR6798, LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1, NTF6B, AC008687.5, CGB5, CGB8, AC008687.6, CGB7, AC008687.8, AC008687.7, AC008687.2, NTF4, AC008687.3, KCNA7, RN7SL708P, SNRNP70, LIN7B, C19orf73, PPFIA3.
- chr20:13,995,369–16,053,197, 1 gene, copy number 12 (within-gene range 2–15): MACROD2.
- chr20:14,884,250–16,770,062, 19 genes, copy number 7–12: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR.

Autosomal genes at a single copy (total copy number 1): 1,415. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
